Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A64Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A64Z-01A (Primary Tumor).

[page 1 of 4]
Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auto. (verified)
Document Title: Histology
Encounter info:

ICD-3
Carcinoma, squamous cell NOS
CHF 8070/3
Site Floor mouth
path C04.9
Hard palate C05.0

* Final Report *

(Verified)

Patient Name:

MRN:

DOB:

Acc #:

Location:

Gender: F

Collected:

Client:

Received:

Submitting Phys:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. MAXILLA, RIGHT, PARTIAL MAXILLECTOMY:

- SQUAMOUS CELL CARCINOMA, WELL-DIFFERENTIATED (3.8 CM).
- DEPTH OF INVASION MEASURES 0.55 CM.
- CARCINOMA INVADES INTO UNDERLYING BONE.
- NO LYMPHOVASCULAR INVASION IDENTIFIED.
- SURGICAL MARGINS ARE NEGATIVE FOR IN SITU AND INVASIVE CARCINOMA.
- SEE SYNOPTIC REPORT.

B. TEETH, EXTRACTION:

- GROSSLY UNREMARKABLE TEETH.
- GROSS EXAMINATION ONLY.

Electronically Signed by

Assisted by:

Printed by:
Printed on:

Page 1 of 4
(Continued)

Criteria	hw 5/5/13	Yes	No
Diagnostic Discrepancy			
HPA Discrepancy			
Case in (circle) - QUALITY DISQUALIFIED			

[page 2 of 4]
Anat Path Reports

* Final Report *

Synoptic Worksheet

A. Right maxillectomy:

Specimen:	Upper gingiva (gum) Hard palate Maxilla
Received:	Fresh
Procedure:	Maxillectomy: RIGHT PARTIAL
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 5.7 cm Additional dimension: 4.4 cm Additional dimension: 2.0 cm
Specimen Laterality:	Right
Tumor Site:	Hard palate Maxilla
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 3.8 cm
Tumor Thickness (pT1 and pT2 tumors):	Tumor thickness: 55 mm Measured from ulcerated surface
Tumor Description:	Ulcerated
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G1: Well differentiated
Microscopic Tumor Extension:	into maxilla bone
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 0.4 Unit of measurement: cm Margin(s): lateral mucosal Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia) Distance from closest margin: 0.4 Unit of measurement: cm Margin(s): lateral mucosal
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
Regional Lymph Nodes (pN):	pNX: Cannot be assessed
Distant Metastasis (pM):	Not applicable

[page 3 of 4]
Anat Path Reports

* Final Report *

Clinical History

Right maxillectomy. Right palate cancer.

Specimen(s) Received

A: Right maxillectomy

B: Teeth

Gross Description

Specimen A is received fresh for intraoperative consultation, labeled "right maxillectomy" along with the patient's name and medical record number. It consists of a segment of maxilla measuring 5.7 x 4.4 x 2.0 cm. The specimen includes three teeth. Within the region of the hard palate there is an ulcerative mass measuring 3.8 x 2.1 cm extending to a depth of 1.0 cm. This mass is located 0.7 cm from the anterior mucosal margin of resection, 0.5 cm from the posterior margin of resection, 0.6 cm from the medial mucosal margin of resection, and 0.4 cm from the lateral mucosal margin of resection. The tumor is located 1.2 cm from the superior bony margin of resection. The tumor is located 2.5 cm from the posterior soft tissue margin of resection. The uninvolved bone and mucosa are grossly unremarkable. The superior bony margin of resection is inked black. Sections are submitted as follows. Representative sections of tumor and normal tissue are submitted for Tumor Banking. (Dictated by -

Specimen B is received fresh, labeled "teeth" along with the patient's name and medical record number. It consists of two teeth measuring 1.3 x 1.0 x 1.0 cm in aggregate. No cassettes are submitted. Dictated by

Cassette Summary:

A1FS:	Anterior lateral margin
A2FS:	Anterior margin
A3FS:	Medial margin
A4FS:	Posterior margin
A5FS:	Posterior lateral margin
A6:	Posterior soft tissue margin of resection
A7:	Mid lateral mucosal margin of resection
A8,9:	Full thickness cross section with deep margin, submitted for decalcification

Intraoperative Consult Diagnosis

A1FS: RIGHT MAXILLA, ANTERIOR LATERAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A2FS: ANTERIOR MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A3FS: MEDIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A4FS: POSTERIOR MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
A5FS: POSTERIOR LATERAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by Dr.

Pathologist:

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding patient

Anat Path Reports

* Final Report *

Printed by:
Printed on:

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file e8017764-d78e-492f-9bfb-0c33bd85efe1 (TCGA-QK-A64Z.C2A57619-3A37-428A-8165-A63FC8725DDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).